Somatic mutation profile of tumor specimen TCGA-EM-A22Q-01A (aliquot TCGA-EM-A22Q-01A-11D-A17V-08) from TCGA case TCGA-EM-A22Q, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.5 years (13,341 days).
Specimen TCGA-EM-A22Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acf40c36-4950-4922-bd83-dfa96a63fe5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22Q-10A (Blood Derived Normal), aliquot TCGA-EM-A22Q-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/490c0bf4-6fa5-4ebc-aea9-7915399d96a0

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 58/164 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- POLR1B | c.3052C>T p.R1018* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV54495916; called by muse, mutect2, varscan2
- RBM7 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs376690569, COSV100348306; called by muse, mutect2, varscan2
- SIPA1L1 | c.5180A>G p.Y1727C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs766184659, COSV62169096; called by muse, mutect2
- ZNF480 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV57995119; called by muse, mutect2, varscan2
- PTBP2 | c.308dup p.N103Kfs*18 (on ENST00000426398 / NM_001300986.2; = p.N95Kfs*18 on NM_021190.4) | Frame Shift Ins (INS) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- FRAS1 | c.5427C>G p.V1809= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV53597319; called by muse, mutect2, varscan2
- MRGPRX1 | c.9A>T p.P3= | Silent (SNP) | VAF 64/185 reads (35%) | catalogued as COSV57106355; called by muse, mutect2, varscan2
- DNM1P46 | n.489G>A | RNA (SNP) | VAF 6/16 reads (38%) | catalogued as rs770427765; called by muse, mutect2, varscan2
